Somatic mutation profile of tumor specimen TARGET-10-PASKXN-09A (aliquot TARGET-10-PASKXN-09A-01D) from TARGET case TARGET-10-PASKXN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,440 days).
Specimen TARGET-10-PASKXN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df0b210b-c46a-4d7e-b95d-2089756fb2b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKXN-14A (Bone Marrow Normal), aliquot TARGET-10-PASKXN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36b139f8-1388-4def-bf38-c543ce0e2f4e

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Ins 2, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANLN | c.2374A>G p.S792G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56079186; called by muse, mutect2, varscan2
- ARHGDIG | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54733582; called by muse, mutect2, varscan2
- COL7A1 | c.4564-2A>G p.X1522_splice | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV60402453; called by muse, mutect2, varscan2
- KDM6A | c.3725G>A p.G1242D | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65039775, COSV65045276; called by muse, mutect2
- MYB | c.1774_1775insT p.P592Lfs*2 | Frame Shift Ins (INS) | VAF 27/76 reads (36%) | catalogued as COSV57201451; called by mutect2, pindel, varscan2
- MYH8 | c.4459G>A p.V1487M | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV67971708; called by muse, mutect2, varscan2
- NOTCH1 | c.5153T>C p.I1718T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53036974, COSV53072017; called by muse, mutect2, varscan2
- OR10H2 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs368469319, COSV99045397; called by muse, mutect2, varscan2
- PCDHGA4 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53894361; called by muse, mutect2
- PCLO | c.6850C>A p.P2284T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV61622321, COSV61650752; called by muse, mutect2, varscan2
- PHF6 | c.715C>T p.H239Y (on ENST00000332070 / NM_032458.3; = p.H240Y on NM_032335.3) | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59706360, COSV99045842; called by muse, mutect2, varscan2
- SYNM | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs5030694, COSV60374570; called by muse, mutect2, varscan2
- ADGRF1 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DHX9 | c.2502C>A p.H834Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.374); called by muse, mutect2
- DIXDC1 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- DNAH7 | c.4216G>T p.A1406S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.061); called by muse, mutect2
- DNM2 | c.1684_1686del p.K562del (on ENST00000355667 / NM_001005360.3; = p.K558del on NM_004945.3) | In Frame Del (DEL) | VAF 66/171 reads (39%) | called by pindel, varscan2
- FAM221A | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- KCNK17 | c.842_843insAGGC p.K282Gfs*2 | Frame Shift Ins (INS) | VAF 45/127 reads (35%) | called by mutect2, pindel, varscan2
- NIPBL | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- REV1 | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ZADH2 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF7 | c.1807C>A p.H603N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO16 | c.5142T>C p.S1714= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- OR4A47 | c.246C>A p.G82= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV71445082; called by muse, mutect2
- PCLO | c.1941C>T p.G647= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs190242317, COSV61644369; called by muse, varscan2
- AL355315.1 | c.346-17440_346-17439insAGG | Intron (INS) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
